Somatic mutation profile of tumor specimen MMRF_2307_1_BM_CD138pos (aliquot MMRF_2307_1_BM_CD138pos_T1_KHS5U_L11023) from MMRF case MMRF_2307, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.5 years (24,294 days).
Specimen MMRF_2307_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 433e282d-6661-4cd5-8eae-78c8c331c338.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2307_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2307_1_PB_WBC_C2_KHS5U_L11024; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15bfaa85-9369-4cf2-8d45-6a85513f9600

The open-access MAF lists 71 somatic variants for this specimen: 23 protein-altering or splice-affecting, 9 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 24, Missense Mutation 21, Silent 9, Intron 8, 5'UTR 3, RNA 3, 3'Flank 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EML1 | c.2204A>G p.E735G | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV99214846; called by muse, mutect2, varscan2
- IGHV2-5 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1555425495; called by muse, varscan2
- LAMA1 | c.2047T>C p.Y683H | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1229740588; called by muse, mutect2, varscan2
- MAP10 | c.1670G>A p.S557N | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.101); catalogued as COSV69364444; called by muse, mutect2, varscan2
- MYO7A | c.4243A>G p.T1415A | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs761755624; called by muse, mutect2, varscan2
- PLOD2 | c.680-1G>C p.X227_splice | Splice Site (SNP) | VAF 10/52 reads (19%) | catalogued as COSV51463070; called by muse, mutect2, varscan2
- PTX4 | c.949G>A p.A317T (on ENST00000447419 / NM_001328608.2; = p.A312T on NM_001013658.1) | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.903); catalogued as rs13332460, COSV53516547; called by muse, mutect2, varscan2
- RAPSN | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs199506866, COSV54085061; called by muse, mutect2, varscan2
- RIN2 | c.1382C>T p.P461L (on ENST00000255006 / NM_001242581.1; = p.P412L on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1283938416; called by muse, mutect2, varscan2
- SLC22A3 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778599126; called by muse, mutect2, varscan2
- SLC6A3 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs761418909, COSV54368242; called by muse, mutect2, varscan2
- TGDS | c.284T>G p.V95G | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV54301030; called by muse, mutect2, varscan2
- TRAF2 | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56040676; called by muse, mutect2, varscan2
- TTI2 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as rs376364988, COSV62452377; called by muse, mutect2, varscan2
- ATF7IP | c.3776A>G p.Q1259R | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAH14 | c.4865C>T p.A1622V (on ENST00000445597; = p.A2027V on NM_001367479.1) | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HBP1 | c.1527+8T>G | Splice Region (SNP) | VAF 33/119 reads (28%) | called by muse, mutect2, varscan2
- NCOA7 | c.2483A>G p.D828G | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OTOL1 | c.593A>G p.D198G | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- RYR3 | c.1040A>G p.K347R | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAS2R1 | c.610C>G p.H204D | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- WDR47 | c.1292G>A p.R431K (on ENST00000369962 / NM_001142551.2; = p.R432K on NM_014969.5) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.97); called by muse, mutect2
- YLPM1 | c.5992G>T p.D1998Y | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDKN3 | c.30T>C p.S10= | Silent (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- F2 | c.735G>T p.L245= | Silent (SNP) | VAF 53/157 reads (34%) | catalogued as COSV100319706; called by muse, mutect2, varscan2
- H2AC6 | c.345G>C p.V115= | Silent (SNP) | VAF 101/359 reads (28%) | catalogued as rs1253301676; called by muse, mutect2, varscan2
- IGLV5-52 | c.339T>C p.Y113= | Silent (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- MAP3K6 | c.2757A>C p.R919= | Silent (SNP) | VAF 24/82 reads (29%) | called by muse, mutect2, varscan2
- PCDH17 | c.1737C>T p.N579= | Silent (SNP) | VAF 90/206 reads (44%) | catalogued as COSV64972042; called by muse, mutect2, varscan2
- PPEF2 | c.1098C>T p.A366= | Silent (SNP) | VAF 27/115 reads (23%) | called by muse, mutect2, varscan2
- PPP1R10 | c.846G>A p.P282= | Silent (SNP) | VAF 54/196 reads (28%) | catalogued as rs923469735; called by muse, mutect2, varscan2
- SEZ6L | c.1653G>A p.A551= | Silent (SNP) | VAF 62/281 reads (22%) | catalogued as rs146077946; called by muse, mutect2, varscan2
- ABCG1 | c.287-14456del | Intron (DEL) | VAF 7/23 reads (30%) | called by mutect2, pindel, varscan2
- AC084879.1 | n.1132C>T | RNA (SNP) | VAF 43/217 reads (20%) | called by muse, mutect2, varscan2
- ACBD3 | c.*42A>G | 3'UTR (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- ADCY4 | c.3082-24T>C | Intron (SNP) | VAF 72/269 reads (27%) | called by muse, mutect2, varscan2
- ARID1A | c.*335T>A | 3'UTR (SNP) | VAF 16/64 reads (25%) | catalogued as rs1376510290; called by muse, varscan2
- CBX5 | c.*6051_*6054del | 3'UTR (DEL) | VAF 14/95 reads (15%) | called by mutect2, pindel, varscan2
- CDC42EP3 | c.*1183T>A | 3'UTR (SNP) | VAF 6/34 reads (18%) | catalogued as COSV54873584; called by muse, mutect2, varscan2
- CDHR1 | c.-63C>T | 5'UTR (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- CXXC4 | c.*2819G>T | 3'UTR (SNP) | VAF 15/69 reads (22%) | called by muse, mutect2, varscan2
- CYCS | c.*2560T>G | 3'UTR (SNP) | VAF 12/68 reads (18%) | called by muse, varscan2
- DTX3L | c.*168T>G | 3'UTR (SNP) | VAF 29/151 reads (19%) | called by mutect2, varscan2
- EPB41 | c.2184+197A>C | Intron (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- FDFT1 | c.*566C>A | 3'UTR (SNP) | VAF 16/68 reads (24%) | catalogued as COSV99594784; called by muse, mutect2, varscan2
- FYTTD1 | c.*283A>G | 3'UTR (SNP) | VAF 28/93 reads (30%) | called by muse, mutect2, varscan2
- IGLV1-41 | n.119G>A | RNA (SNP) | VAF 38/85 reads (45%) | catalogued as rs1269161260; called by muse, mutect2, varscan2
- IL20 | c.*122G>T | 3'UTR (SNP) | VAF 96/381 reads (25%) | called by muse, mutect2, varscan2
- KDM5A | c.*5293T>A | 3'UTR (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- KLHL42 | c.*2032A>G | 3'UTR (SNP) | VAF 23/91 reads (25%) | catalogued as rs770325157; called by muse, mutect2, varscan2
- LDB3 | c.896+6820C>T | Intron (SNP) | VAF 138/586 reads (24%) | called by muse, mutect2, varscan2
- LRRC8D | c.*61G>A | 3'UTR (SNP) | VAF 54/211 reads (26%) | catalogued as rs1305113212, COSV100487656, COSV61578408; called by muse, mutect2, varscan2
- MIR5195 | n.15G>C | RNA (SNP) | VAF 43/120 reads (36%) | called by muse, mutect2, varscan2
- NGDN | c.12+69G>A | Intron (SNP) | VAF 35/154 reads (23%) | called by muse, mutect2, varscan2
- PCDHA10 | c.2388+3308G>A | Intron (SNP) | VAF 16/52 reads (31%) | catalogued as rs1389078049; called by muse, mutect2, varscan2
- PDK4 | c.*289T>G | 3'UTR (SNP) | VAF 41/149 reads (28%) | called by muse, mutect2, varscan2
- PPP2R2A | c.8-34A>C | Intron (SNP) | VAF 34/148 reads (23%) | called by muse, mutect2, varscan2
- RAB2A | c.*777A>C | 3'UTR (SNP) | VAF 26/118 reads (22%) | called by muse, mutect2, varscan2
- RARG | c.*391_*392del | 3'UTR (DEL) | VAF 23/163 reads (14%) | called by mutect2, pindel, varscan2
- SESN3 | c.-133C>A | 5'UTR (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- SHF | c.303+70A>T | Intron (SNP) | VAF 24/86 reads (28%) | catalogued as rs1284243765; called by mutect2, varscan2
- SLC12A2 | c.*2123A>T | 3'UTR (SNP) | VAF 6/42 reads (14%) | catalogued as rs1037473350, COSV52474636; called by muse, varscan2
- SLC22A9 | c.-151C>A | 5'UTR (SNP) | VAF 14/95 reads (15%) | called by muse, mutect2, varscan2
- SLC41A2 | c.*216A>C | 3'UTR (SNP) | VAF 18/71 reads (25%) | called by muse, mutect2, varscan2
- SLC45A4 | c.*3094G>A | 3'UTR (SNP) | VAF 25/125 reads (20%) | catalogued as rs1405879064; called by muse, mutect2, varscan2
- SLC46A3 | c.*25dup | 3'UTR (INS) | VAF 39/114 reads (34%) | catalogued as rs763393019; called by mutect2, varscan2
- SLC5A6 | c.*782del | 3'UTR (DEL) | VAF 15/119 reads (13%) | called by mutect2, pindel, varscan2
- SLCO1B3 | c.*301A>G | 3'UTR (SNP) | VAF 34/111 reads (31%) | called by muse, mutect2, varscan2
- TNFRSF11A | c.*1908T>C | 3'UTR (SNP) | VAF 36/114 reads (32%) | called by muse, mutect2, varscan2
- UBE4A | c.*2225T>G | 3'UTR (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2
- ZBTB38 | chr3:141446414 C>T | 3'Flank (SNP) | VAF 32/144 reads (22%) | catalogued as rs368089863; called by muse, mutect2, varscan2
